Gene-level copy-number profile of specimen HCM-SANG-1326-C15-85A-01D-A80T-32 from HCMI case HCM-SANG-1326-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2.
Specimen HCM-SANG-1326-C15-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c8235f52-b6f8-49c0-9867-81af826fd308.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1326-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,724 have no estimate.
https://portal.gdc.cancer.gov/files/ccc5fece-d165-4731-8cae-3e40d978019a

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 1,720; copy number 2: 17,235; copy number 3: 26,995; copy number 4: 11,386; copy number 5: 1,084; copy number 6: 143; copy number 7: 27; copy number 8: 7; copy number 9: 153; copy number 10: 43; copy number 13: 2; copy number 23: 3; copy number 24: 6; copy number 25: 14; copy number 26: 3; copy number 28: 6; copy number 44: 13; copy number 46: 1; copy number 47: 21; copy number 49: 3; copy number 50: 1; copy number 52: 14; copy number 241: 16.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:4,117,925–4,150,421, 3 genes: AC116562.1, OR7E103P, UNC93B4.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 333 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,887,022–89,916,052, 3 genes, copy number 7–13: IGKV2D-36, IGKV1D-35, IGKV1D-33.
- chr3:37,052,626–37,183,689, 1 gene, copy number 52 (within-gene range 2–52): LRRFIP2.
- chr3:37,134,658–37,440,186, 11 genes, copy number 46–52: UBE2D3P2, RNU6-1301P, UBE2FP1, AC126118.1, AC097359.1, AC097359.3, AC097359.2, GOLGA4, TCEA1P2, RNA5SP129, C3orf35.
- chr3:37,861,880–38,649,687, 24 genes, copy number 47–49: CTDSPL, MIR26A1, VILL, PLCD1, Y_RNA, DLEC1, PPP2R2DP1, ACAA1, Y_RNA, MYD88, OXSR1, SLC22A13, AP006193.1, SLC22A14, RNU6-235P, DLEC1P1, XYLB, ACVR2B-AS1, ACVR2B, EXOG, Y_RNA, DDTP1, RPL18AP7, SCN5A.
- chr3:39,052,013–39,287,920, 13 genes, copy number 44: WDR48, GORASP1, TTC21A, MIR6822, CSRNP1, AC092053.3, AC092053.2, Metazoa_SRP, XIRP1, AC092053.6, DSTNP4, CX3CR1, AC092053.1.
- chr3:40,970,541–41,260,096, 4 genes, copy number 52 (within-gene range 2–52): AC099541.1, AC009743.1, MRPS31P1, CTNNB1.
- chr7:98,846,488–99,504,857, 22 genes, copy number 7 (within-gene range 3–7): TMEM130, TRRAP, MIR3609, AC004893.2, RNF14P3, SMURF1, AC004893.1, KPNA7, MYH16, AC004834.1, AC004922.1, ARPC1A, ARPC1B, PDAP1, BUD31, PTCD1, ATP5MF-PTCD1, CPSF4, AC073063.1, ATP5MF, ZNF789, ZNF394.
- chr9:30,388,935–36,677,683, 204 genes, copy number 7–10 (broad region; genes not listed).
- chr9:64,810,865–64,811,429, 1 gene, copy number 8: BNIP3P4.
- chr9:65,189,995–65,230,861, 3 genes, copy number 23: BMS1P12, AL512605.1, AL512605.2.
- chr10:120,354,701–121,615,839, 16 genes, copy number 241: RPL21P16, AC073587.1, PLPP4, LINC01561, AC023282.1, WDR11-AS1, AL391425.1, WDR11, AC010998.2, AC010998.1, AC010998.3, RPL19P16, LINC01153, RN7SKP167, FGFR2, AC009988.1.
- chr18:21,650,901–22,647,688, 31 genes, copy number 7–28: ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P.

Autosomal genes at a single copy (total copy number 1): 1,379. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
